Somatic mutation profile of tumor specimen TCGA-13-0912-01A (aliquot TCGA-13-0912-01A-01W-0421-09) from TCGA case TCGA-13-0912, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.7 years (21,427 days).
Specimen TCGA-13-0912-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1224b835-1a80-433e-9895-c2a4a4807dc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0912-10A (Blood Derived Normal), aliquot TCGA-13-0912-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/955bf9e7-9d01-4d3e-b5da-62bc0e13219f

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 27, Silent 14, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 53/57 reads (93%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 204/414 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV52976351; called by muse, mutect2, varscan2
- AGAP1 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs969395658, COSV58320528; called by muse, mutect2, varscan2
- ANKRD27 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs201398434, COSV60131683; called by muse, mutect2, varscan2
- ARSI | c.917dup p.S307Qfs*43 | Frame Shift Ins (INS) | VAF 6/64 reads (9%) | catalogued as rs747762689; called by pindel, varscan2
- ASIC4 | c.1101G>T p.M367I (on ENST00000347842 / NM_182847.3; = p.M386I on NM_018674.6) | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV61731828; called by muse, mutect2, varscan2
- ATP11C | c.2239C>T p.H747Y | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59564061; called by muse, mutect2, varscan2
- EPHA1 | c.2776C>G p.R926G | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as CM1512494, COSV51971277; called by muse, mutect2, varscan2
- FAT3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 86/153 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs1001662868, COSV53111028; called by muse, mutect2, varscan2
- FBXO9 | c.508del p.Q170Rfs*27 | Frame Shift Del (DEL) | VAF 33/94 reads (35%) | catalogued as COSV99762258; called by mutect2, pindel, varscan2
- GNB2 | c.302T>C p.M101T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV51941879; called by muse, mutect2, varscan2
- HESX1 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 140/300 reads (47%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV55843274; called by muse, mutect2, varscan2
- IL17RB | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 93/185 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55472930; called by muse, mutect2, varscan2
- KIF4B | c.1751C>A p.T584K | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV70529325; called by muse, mutect2
- KMT2A | c.6988A>G p.K2330E | Missense Mutation (SNP) | VAF 157/327 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as COSV63285850; called by muse, mutect2, varscan2
- LLGL2 | c.1002_1016del p.F335_T339del | In Frame Del (DEL) | VAF 10/12 reads (83%) | catalogued as COSV51352811; called by mutect2, varscan2
- MCM5 | c.1702G>T p.V568L | Missense Mutation (SNP) | VAF 72/79 reads (91%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53346273; called by muse, mutect2, varscan2
- NEK10 | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs370504122; called by muse, mutect2, varscan2
- NLGN1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.555); catalogued as COSV100849516; called by muse, mutect2
- NR1H4 | c.905C>T p.T302M (on ENST00000551379 / NM_001206993.2; = p.T288M on NM_005123.4) | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs748378207, COSV51852131; called by muse, mutect2, varscan2
- NUP205 | c.1121A>T p.E374V | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV53659299; called by muse, mutect2, varscan2
- PCDHB2 | c.2192A>T p.E731V | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as COSV99165556; called by muse, mutect2, varscan2
- PLIN2 | c.1187C>A p.T396K | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52802571, COSV52803264; called by muse, mutect2, varscan2
- SGSM1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 67/83 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1361949539, COSV68508552, COSV68512419; called by muse, mutect2, varscan2
- SH3RF2 | c.1987G>A p.G663R | Missense Mutation (SNP) | VAF 187/353 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs142456711; called by muse, mutect2, varscan2
- WDR5B | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 155/291 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); catalogued as COSV51658132; called by muse, mutect2, varscan2
- ZZZ3 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 138/331 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV66232760; called by muse, mutect2, varscan2
- ASXL1 | c.2920dup p.Y974Lfs*8 | Frame Shift Ins (INS) | VAF 43/107 reads (40%) | called by mutect2, pindel, varscan2
- COL14A1 | c.2978A>T p.E993V | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2
- MUC5B | c.7124A>G p.Q2375R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYO9A | c.1090C>G p.L364V | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2
- PAAF1 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2
- DNAH1 | c.3573C>T p.D1191= | Silent (SNP) | VAF 88/172 reads (51%) | catalogued as rs541334137, COSV70229070; ClinVar: likely benign; called by muse, mutect2, varscan2
- FKBP5 | c.111C>G p.V37= | Silent (SNP) | VAF 60/118 reads (51%) | catalogued as COSV61881762; called by muse, mutect2, varscan2
- IGSF22 | c.2325T>A p.V775= (on ENST00000319338; = p.V876= on NM_173588.4) | Silent (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- ITPRID1 | c.858C>T p.P286= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as rs1278810096, COSV60074915; called by muse, mutect2, varscan2
- MAP1B | c.858C>T p.G286= | Silent (SNP) | VAF 171/381 reads (45%) | catalogued as rs777817448, COSV57099167; called by muse, mutect2, varscan2
- OXSM | c.972C>G p.A324= | Silent (SNP) | VAF 88/156 reads (56%) | catalogued as COSV55001527; called by muse, mutect2, varscan2
- PCDHB9 | c.1341C>T p.N447= | Silent (SNP) | VAF 95/172 reads (55%) | catalogued as rs1459171550, COSV53376231; called by muse, mutect2, varscan2
- PDE11A | c.2070C>G p.T690= | Silent (SNP) | VAF 20/217 reads (9%) | catalogued as rs758882128, COSV53692777, COSV99610753, COSV99613144; called by muse, mutect2
- PRKAR1B | c.663C>T p.L221= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100816738; called by muse, mutect2, varscan2
- RGS7 | c.87C>T p.D29= | Silent (SNP) | VAF 72/141 reads (51%) | catalogued as rs563733368, COSV58542082; called by muse, mutect2, varscan2
- SNX33 | c.1287G>A p.Q429= | Silent (SNP) | VAF 84/201 reads (42%) | catalogued as COSV57913528; called by muse, mutect2, varscan2
- THADA | c.4488A>T p.G1496= | Silent (SNP) | VAF 58/115 reads (50%) | catalogued as COSV57683734; called by muse, mutect2, varscan2
- TTC38 | c.633G>T p.P211= | Silent (SNP) | VAF 33/42 reads (79%) | catalogued as COSV66844225; called by muse, mutect2, varscan2
- ZNF813 | c.1068G>A p.K356= | Silent (SNP) | VAF 337/755 reads (45%) | catalogued as COSV67176551; called by muse, mutect2, varscan2
